Somatic mutation profile of tumor specimen C3L-01639-01 (aliquot CPT0091780009) from CPTAC case C3L-01639, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 71.6 years (26,166 days).
Specimen C3L-01639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 076e3693-ba90-4d3c-b00e-b43be4fa01cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01639-31 (Blood Derived Normal), aliquot CPT0093660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/540c73f3-03f2-4ffb-8a45-28e0498ad156

The open-access MAF lists 550 somatic variants for this specimen: 355 protein-altering or splice-affecting, 131 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 131, Frame Shift Del 51, Intron 33, Nonsense Mutation 17, Frame Shift Ins 11, 3'UTR 11, RNA 10, Splice Site 7, 5'UTR 6, 5'Flank 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- ETFA | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 112/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119458970, CM920245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 23/210 reads (11%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 9/180 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3R2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886041602, COSV55847404; ClinVar: pathogenic; called by muse, mutect2
- PRSS56 | c.1066del p.Q356Rfs*148 | Frame Shift Del (DEL) | VAF 26/219 reads (12%) | catalogued as rs730882064; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 145/518 reads (28%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 60/614 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs778851184; called by muse, mutect2
- ABO | c.239+1G>A p.X80_splice | Splice Site (SNP) | VAF 6/97 reads (6%) | catalogued as rs781912667, COSV71743441; called by muse, mutect2
- ADAMTS15 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769395017, COSV54508940; called by muse, mutect2, varscan2
- AJM1 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs367628747; called by muse, mutect2
- AKR7A3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 37/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780744277, COSV64389285; called by muse, mutect2
- ANK2 | c.11729C>T p.S3910F | Missense Mutation (SNP) | VAF 151/447 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52152551; called by muse, mutect2, varscan2
- APOL6 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.87); catalogued as rs560610184; called by muse, mutect2, varscan2
- ATAD5 | c.3295del p.R1099Efs*12 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | catalogued as COSV58972174; called by pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 22/197 reads (11%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCS1L | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 53/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829270; called by muse, mutect2
- BTBD16 | c.729del p.T244Rfs*17 | Frame Shift Del (DEL) | VAF 33/248 reads (13%) | catalogued as rs774408792; called by pindel, varscan2
- BTC | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV67547696; called by muse, mutect2, varscan2
- BTD | c.1068G>T p.Q356H | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV100329399; called by muse, mutect2
- CACNG7 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.077); catalogued as rs758644909; called by muse, mutect2, varscan2
- CBLL1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV56029048; called by muse, mutect2
- CD300LB | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs546240009; called by muse, mutect2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH15 | c.152del p.P51Rfs*70 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV57022654; called by mutect2, pindel, varscan2
- CDH4 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as rs147810745, COSV64643575; called by muse, mutect2, varscan2
- CDRT15 | c.325T>C p.W109R | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.781); catalogued as rs770108402; called by muse, mutect2, varscan2
- CENPF | c.5926G>A p.A1976T | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1275494472; called by muse, mutect2
- CEP97 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs767173679, COSV59123277; called by muse, mutect2
- CKAP2 | c.463A>G p.K155E (on ENST00000378037 / NM_001098525.2; = p.K154E on NM_018204.5) | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs1397046593; called by muse, mutect2, varscan2
- CLDN9 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs377171800; called by muse, mutect2, varscan2
- COL4A1 | c.1802G>C p.G601A | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1218480942, COSV65422990; called by muse, mutect2, varscan2
- CPZ | c.339G>A p.W113* (on ENST00000360986 / NM_001014447.3; = p.W102* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV59922817; called by muse, varscan2
- CSDC2 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs918690411; called by muse, mutect2, varscan2
- CSMD3 | c.3946C>T p.R1316C (on ENST00000297405 / NM_001363185.1; = p.R1212C on NM_052900.3) | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs1049829056, COSV52170361, COSV52249274, COSV52271911; called by muse, mutect2
- CYP4F12 | c.1358G>T p.R453M | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV61172408; called by muse, mutect2, varscan2
- CYP4F3 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 116/447 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV55410079; called by muse, mutect2, varscan2
- DNAJC17 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1352219038; called by muse, mutect2
- DOT1L | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs1005372612; called by muse, mutect2
- DYNC2H1 | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs372627366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 28/240 reads (12%) | catalogued as rs773311790; called by mutect2, pindel
- EHMT1 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as rs1484647206, COSV58382865; called by muse, mutect2
- EP400 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.229); catalogued as rs1361086921; called by muse, mutect2, varscan2
- EPS8L1 | c.1087C>G p.P363A (on ENST00000201647 / NM_133180.3; = p.P236A on NM_017729.3) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99135813; called by muse, mutect2
- ERAP1 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57091873; called by muse, mutect2, varscan2
- ERRFI1 | c.916dup p.T306Nfs*6 | Frame Shift Ins (INS) | VAF 99/460 reads (22%) | catalogued as rs1212152375; called by mutect2, pindel, varscan2
- EZH1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70549159; called by muse, mutect2, varscan2
- F2R | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs1346475435; called by muse, mutect2, varscan2
- FAHD2B | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 22/205 reads (11%) | catalogued as rs775549903; called by muse, mutect2, varscan2
- FAM120AOS | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs927012067; called by muse, mutect2, varscan2
- FAM149A | c.2087G>A p.G696D (on ENST00000356371 / NM_001367768.2; = p.G405D on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.12); catalogued as rs763114143; called by muse, mutect2
- FAM222A | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1188185382; called by muse, mutect2
- FAM47B | c.1589G>T p.R530M | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100264315; called by muse, mutect2, varscan2
- FILIP1 | c.384C>G p.H128Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs778523176, COSV52737253; called by muse, mutect2, varscan2
- FOXK1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61067197; called by muse, mutect2, varscan2
- GAL3ST3 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs1219816338, COSV61749204; called by muse, mutect2, varscan2
- GBF1 | c.4972G>A p.A1658T (on ENST00000369983 / NM_001377137.1; = p.A1657T on NM_004193.3) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs568068401, COSV64146392; called by muse, mutect2
- GHSR | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV53840842; called by muse, mutect2, varscan2
- GPR68 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as rs1414869163, COSV53177003; called by muse, mutect2
- GRM7 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63143657; called by muse, mutect2, varscan2
- GTF2IRD2B | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV100441313; called by muse, mutect2
- HAS1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs777913003; called by muse, mutect2, varscan2
- HNF4G | c.849del p.R284Gfs*19 (on ENST00000354370 / NM_001330561.2; = p.R331Gfs*19 on NM_004133.5) | Frame Shift Del (DEL) | VAF 43/416 reads (10%) | catalogued as COSV62966547; called by mutect2, pindel
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGAX | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51649230; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 24/282 reads (9%) | catalogued as rs754892524; called by mutect2, pindel
- KCNB1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407696419; called by muse, mutect2
- KLC4 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs201506218, COSV52437929; called by muse, mutect2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2, varscan2
- KSR2 | c.554dup p.E186Gfs*200 | Frame Shift Ins (INS) | VAF 20/189 reads (11%) | catalogued as rs777127484; called by mutect2, varscan2
- KY | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs752972538; called by muse, mutect2, varscan2
- LAG3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV52568977; called by muse, mutect2, varscan2
- LCOR | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs140995155; called by muse, mutect2
- LRRC8E | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100142682; called by muse, mutect2
- LSM14B | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 9/238 reads (4%) | catalogued as rs1229215264, COSV99444269; called by muse, mutect2
- MAP3K3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 34/421 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs773083246; called by muse, mutect2
- MAPK6 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99959587; called by muse, mutect2, varscan2
- MED12 | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100380168; called by muse, mutect2
- MMP14 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763632539; called by muse, mutect2, varscan2
- MROH1 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 35/464 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.196); catalogued as rs972139035; called by muse, mutect2
- MRTFB | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1348671625; called by muse, mutect2
- MYH3 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747837966; called by muse, mutect2, varscan2
- MYO9B | c.6143C>T p.P2048L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs768893704, COSV55727647; called by muse, mutect2, varscan2
- MYPOP | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59133921; called by muse, mutect2, varscan2
- NAA25 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs776147529, COSV99927499; called by muse, mutect2, varscan2
- NADK | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746695294; called by muse, mutect2, varscan2
- NEFH | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1469426243; called by muse, mutect2, varscan2
- NR1H3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60623544; called by muse, mutect2
- NRXN2 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs761000700; called by mutect2, varscan2
- NT5DC2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200773348, COSV58740933; called by muse, mutect2, varscan2
- NWD1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs377718201, COSV60348273; called by muse, mutect2
- OPLAH | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs782222600; called by muse, mutect2
- OR13A1 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100981053; called by muse, mutect2
- OR51E1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs549241325; called by muse, mutect2, varscan2
- OR5D14 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100162178; called by muse, mutect2
- OR8J3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1565055870; called by muse, mutect2
- PARM1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1039671801, COSV56649794; called by muse, mutect2
- PCDHB1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1554267318, COSV60633061; called by muse, mutect2, varscan2
- PCDHGA6 | c.1609A>G p.S537G | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV53983947; called by muse, mutect2
- PID1 | c.494G>A p.R165H (on ENST00000354069 / NM_001330156.1; = p.R163H on NM_017933.5) | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764931966, COSV62483420; called by muse, mutect2, varscan2
- PIGT | c.1099del p.E367Sfs*2 | Frame Shift Del (DEL) | VAF 18/220 reads (8%) | catalogued as rs1398799598; called by mutect2, pindel
- PIK3CA | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV55892983, COSV55969135, COSV55978933; called by muse, mutect2
- PKD1 | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs144610067; called by muse, mutect2
- PKP4 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748941464; called by muse, mutect2
- PLCB2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760528362; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | catalogued as rs751873496; called by mutect2, pindel
- POLG | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.894); catalogued as rs771576687; called by muse, mutect2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 19/171 reads (11%) | catalogued as rs745933237; called by mutect2, pindel
- PPP1R26 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1418181978; called by muse, mutect2, varscan2
- PRG2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1461598717, COSV100314925; called by muse, mutect2
- PRKDC | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as COSV58059167; called by muse, mutect2, varscan2
- PRKG2 | c.1832G>A p.C611Y | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52327374; called by muse, mutect2
- PTAR1 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201402192; called by muse, mutect2
- PTEN | c.183del p.H61Qfs*38 | Frame Shift Del (DEL) | VAF 66/234 reads (28%) | catalogued as COSV64289119, COSV99057944; called by mutect2, pindel, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB23 | c.239del p.R80Qfs*28 | Frame Shift Del (DEL) | VAF 53/260 reads (20%) | catalogued as COSV58097253; called by mutect2, pindel, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | catalogued as rs748033282; called by mutect2, varscan2
- RASA1 | c.2126G>C p.R709P | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV57201356; called by muse, varscan2
- RBMS3 | c.1067G>T p.R356M (on ENST00000383767 / NM_001003793.3; = p.R338M on NM_001003792.3) | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV56136066; called by muse, mutect2
- RBMX2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs377526825; called by muse, varscan2
- RETREG1 | c.1023A>T p.E341D (on ENST00000306320 / NM_001034850.2; = p.E200D on NM_019000.4) | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100103999; called by muse, mutect2, varscan2
- RFNG | c.663-3del | Splice Region (DEL) | VAF 11/78 reads (14%) | catalogued as rs1197699009; called by mutect2, pindel, varscan2
- RIPK4 | c.1987G>A p.G663R (on ENST00000352483; = p.G615R on NM_020639.3) | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773928153, COSV60191799; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 28/224 reads (13%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RPS6KA6 | c.2119A>C p.M707L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53119200; called by muse, mutect2
- RRBP1 | c.3839C>T p.A1280V (on ENST00000377813 / NM_001365613.2; = p.A847V on NM_004587.3) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs776275268, COSV99853724; called by muse, mutect2, varscan2
- RXFP4 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1408739914; called by muse, mutect2
- SALL3 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs751561264; called by muse, mutect2, varscan2
- SBK1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs1004434324; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 41/176 reads (23%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEPTIN8 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs1005744499, COSV51525144; called by muse, mutect2
- SETD1B | c.638T>A p.I213N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as COSV99930591; called by muse, mutect2
- SGCA | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 43/438 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as rs368243053; ClinVar: uncertain significance; called by muse, mutect2
- SH3GLB1 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65280284; called by muse, mutect2, varscan2
- SIVA1 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as rs376915360; called by muse, mutect2, varscan2
- SLC35B2 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1316195499, COSV51491932; called by muse, mutect2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 25/204 reads (12%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMARCA4 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1222542093; called by muse, mutect2, varscan2
- SRBD1 | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55406335; called by muse, mutect2
- STK10 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1387514912; called by muse, mutect2, varscan2
- STX11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1449481982, COSV62450809; called by muse, mutect2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/157 reads (10%) | catalogued as rs770033147; called by mutect2, pindel
- TAB3 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.135); catalogued as rs752852470, COSV55835064; called by muse, mutect2
- TAOK2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.756); catalogued as rs865791050; called by muse, mutect2
- TBX3 | c.1522G>A p.A508T (on ENST00000257566 / NM_016569.4; = p.A488T on NM_005996.4) | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs994091095; called by muse, mutect2
- TBX3 | c.1174G>A p.A392T (on ENST00000257566 / NM_016569.4; = p.A372T on NM_005996.4) | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99984158; called by muse, mutect2, varscan2
- TCHH | c.5513G>A p.R1838Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV64274051; called by muse, mutect2
- TDRD15 | c.4698del p.K1566Nfs*14 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as rs750572471; called by mutect2, varscan2
- TMEM171 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763131647; called by muse, mutect2, varscan2
- TMEM59 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1361425916, COSV52373669; called by muse, mutect2, varscan2
- TNIK | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99460020; called by muse, mutect2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TRIM71 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67471470; called by muse, mutect2
- TRIM72 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.305); catalogued as COSV59066762; called by muse, mutect2, varscan2
- TTLL12 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs778481013, COSV99333862; called by muse, mutect2
- TTN | c.79265G>A p.R26422H (on ENST00000591111; = p.R18998H on NM_003319.4) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | PolyPhen benign (0); catalogued as rs570847832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 34/306 reads (11%) | catalogued as rs763652408; called by mutect2, varscan2
- USP24 | c.6655C>T p.R2219* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as rs769648756; called by muse, mutect2, varscan2
- VAX2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs782299811, COSV52266213; called by muse, mutect2
- VRTN | c.2024G>A p.S675N | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV56441457; called by muse, mutect2, varscan2
- VWF | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs757353387, COSV54613300; called by muse, mutect2
- WDR26 | c.869A>G p.H290R (on ENST00000414423 / NM_001379403.1; = p.H190R on NM_025160.7) | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs1033546569; called by muse, mutect2
- WDR45 | c.326G>A p.R109H (on ENST00000376372 / NM_001029896.2; = p.R110H on NM_007075.3) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs782329150; called by muse, mutect2
- WWP1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.103); catalogued as COSV55358328; called by muse, mutect2, varscan2
- YBX3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs1032991280, COSV54384509; called by muse, mutect2, varscan2
- ZFPM2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781567366, COSV65873449; called by muse, mutect2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 30/204 reads (15%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF629 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52697895; called by muse, mutect2
- ABCA13 | c.9241A>T p.T3081S | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AC008397.2 | c.-209-1G>A | Splice Site (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- AC245033.1 | c.1492A>G p.K498E | Missense Mutation (SNP) | VAF 56/612 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- ACOT11 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTA1 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2
- ADAMTSL1 | c.3464del p.G1155Efs*42 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel, varscan2
- AGAP1 | c.386dup p.E130Gfs*20 | Frame Shift Ins (INS) | VAF 16/151 reads (11%) | called by mutect2, pindel
- AKAP10 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 19/257 reads (7%) | called by muse, mutect2
- AKR1D1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK2 | c.7970G>A p.S2657N | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2
- ANKRD17 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AOC3 | c.1241A>G p.H414R | Missense Mutation (SNP) | VAF 85/291 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- APBA3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- APLP2 | c.1872dup p.G625Rfs*20 | Frame Shift Ins (INS) | VAF 36/368 reads (10%) | called by mutect2, pindel
- ARHGAP35 | c.4091T>A p.F1364Y | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARID1A | c.4437_4464del p.M1480Lfs*16 | Frame Shift Del (DEL) | VAF 130/442 reads (29%) | called by mutect2, pindel
- ATF7IP | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP10D | c.3498G>T p.L1166F | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ATP9A | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- BCAR3 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- BMF | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- BMP2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BRAP | c.1566del p.D523Ifs*79 | Frame Shift Del (DEL) | VAF 43/374 reads (11%) | called by mutect2, pindel, varscan2
- C19orf33 | c.319T>G p.*107Gext*8 | Nonstop Mutation (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- CACNA1A | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, varscan2
- CALD1 | c.1586A>C p.Q529P (on ENST00000361675 / NM_033138.4; = p.Q274P on NM_004342.7) | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- CAPN2 | c.1317+2T>C p.X439_splice | Splice Site (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- CBLB | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC18 | c.2294A>G p.Y765C (on ENST00000343253 / NM_001306076.1; = p.Y766C on NM_206886.4) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, varscan2
- CCDC40 | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 23/307 reads (7%) | called by muse, mutect2
- CCDC61 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.367); called by muse, mutect2
- CCT5 | c.1541dup p.Q515Afs*11 | Frame Shift Ins (INS) | VAF 40/402 reads (10%) | called by mutect2, pindel
- CDC14A | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK5RAP2 | c.2107-4G>A | Splice Region (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- CELSR3 | c.6893T>C p.L2298P | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CELSR3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- CNTRL | c.4658A>G p.D1553G | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- COL1A1 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2
- COL4A4 | c.4631C>T p.A1544V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CPNE7 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CSTF3 | c.74T>G p.L25* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | called by muse, varscan2
- CYP2W1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DCAF4L1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- DCAF8 | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- DDHD2 | c.1895T>C p.V632A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- DDX50 | c.625del p.S209Afs*19 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel
- DMGDH | c.962A>C p.Q321P | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DMXL2 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH12 | c.5431C>A p.P1811T (on ENST00000351747; = p.P1830T on NM_001366028.2) | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); called by muse, mutect2
- DNAJB13 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DROSHA | c.1260C>A p.N420K | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DYRK1A | c.256del p.R86Vfs*8 | Frame Shift Del (DEL) | VAF 77/293 reads (26%) | called by pindel, varscan2
- E2F1 | c.680_681del p.C227Yfs*12 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | called by mutect2, pindel, varscan2
- EIF2S3 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EMSY | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- ERRFI1 | c.356_357del p.T119Sfs*28 | Frame Shift Del (DEL) | VAF 48/178 reads (27%) | called by pindel, varscan2
- FAM47C | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- FER1L5 | c.3956C>T p.S1319F (on ENST00000623019; = p.S1292F on NM_001293083.2) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FJX1 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- FKBP15 | c.2729G>A p.G910D | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSIP2 | c.18704C>T p.T6235I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2
- FYCO1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- G6PC2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDF3 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GIMAP5 | c.782G>T p.R261M | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GNPAT | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPR183 | c.722del p.K241Rfs*28 | Frame Shift Del (DEL) | VAF 27/318 reads (8%) | called by mutect2, pindel
- GRM5 | c.2778dup p.Q927Afs*76 (on ENST00000305447 / NM_001143831.2; = p.Q895Afs*76 on NM_000842.4) | Frame Shift Ins (INS) | VAF 56/501 reads (11%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 24/203 reads (12%) | called by pindel, varscan2
- HLA-DQB2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 30/351 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2
- HPD | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- HPSE | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- HTR3E | c.922A>G p.I308V (on ENST00000415389 / NM_001256613.1; = p.I323V on NM_182589.2) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- INCENP | c.1730G>T p.R577L (on ENST00000394818 / NM_001040694.2; = p.R573L on NM_020238.3) | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IRS4 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IZUMO3 | c.104T>C p.L35S | Missense Mutation (SNP) | VAF 37/472 reads (8%) | SIFT deleterious (0.04); called by muse, mutect2
- KCNA10 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNA5 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KCNH8 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.048); called by muse, mutect2
- KIAA0825 | c.2301del p.F767Lfs*27 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.2862dup p.N955Qfs*5 | Frame Shift Ins (INS) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- KIF26B | c.2477G>T p.R826M | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF2A | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- KIRREL3 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KLHL9 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KRT84 | c.1738A>G p.S580G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.899); called by muse, mutect2
- LHCGR | c.467G>C p.C156S | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LRRCC1 | c.1591del p.M531Wfs*13 | Frame Shift Del (DEL) | VAF 20/206 reads (10%) | called by mutect2, pindel
- LRRK2 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 62/475 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP6 | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2
- MCM3AP | c.3683C>G p.T1228S | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2
- MEAK7 | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- MEX3A | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MORF4L2 | c.203del p.P68Lfs*5 | Frame Shift Del (DEL) | VAF 20/188 reads (11%) | called by mutect2, varscan2
- MPRIP | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); called by muse, mutect2
- MROH9 | c.480+2dup p.X160_splice | Splice Site (INS) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- MYH9 | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO6 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NBEAL2 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2
- NBPF12 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 48/533 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.365); called by muse, mutect2
- NCAM2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.16264G>A p.D5422N | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2
- NEFM | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.203); called by muse, mutect2
- NKPD1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- NOL6 | c.1916del p.G639Afs*10 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- NOTCH2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 33/364 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NPBWR1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- NRG1 | c.1444A>G p.T482A (on ENST00000405005 / NM_013964.5; = p.T487A on NM_013956.5) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.669); called by muse, mutect2
- NUDT22 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.125); called by muse, mutect2
- NUF2 | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- NUP188 | c.4137+4_4137+7del p.X1379_splice | Splice Site (DEL) | VAF 31/246 reads (13%) | called by mutect2, pindel
- ODC1 | c.657dup p.D220* | Frame Shift Ins (INS) | VAF 12/132 reads (9%) | called by mutect2, pindel
- OLFM1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR10G3 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14C36 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OTOG | c.7535G>A p.C2512Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- OVGP1 | c.1998del p.E667Kfs*30 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- P2RX3 | c.1066A>T p.K356* | Nonsense Mutation (SNP) | VAF 37/150 reads (25%) | called by muse, varscan2
- PCDHB6 | c.717del p.E240Sfs*29 | Frame Shift Del (DEL) | VAF 28/284 reads (10%) | called by mutect2, pindel
- PCDHGB4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCNX3 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); called by muse, mutect2
- PDE8B | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 54/526 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD2 | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- PHF3 | c.5045C>A p.P1682H | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PIK3R1 | c.2093A>G p.Y698C (on ENST00000521381 / NM_181523.3; = p.Y428C on NM_181504.4) | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1L1 | c.7306G>T p.G2436W | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POLE | c.6003A>G p.S2001= | Splice Region (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- PRAMEF17 | c.600A>T p.K200N | Missense Mutation (SNP) | VAF 126/483 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PTPN21 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRT | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- RANBP2 | c.9491G>A p.G3164D | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- RBL1 | c.2631+1G>C p.X877_splice | Splice Site (SNP) | VAF 53/214 reads (25%) | called by muse, mutect2, varscan2
- RBM19 | c.2857A>G p.S953G | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2
- RDH11 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REST | c.1628dup p.K544Efs*11 | Frame Shift Ins (INS) | VAF 20/203 reads (10%) | called by mutect2, pindel
- RETSAT | c.1759A>T p.I587F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- RIDA | c.290_293del p.K97Sfs*29 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- RNF213 | c.9541G>A p.E3181K | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ROR2 | c.601del p.E201Rfs*12 | Frame Shift Del (DEL) | VAF 50/529 reads (9%) | called by mutect2, pindel
- SALL3 | c.464del p.P155Qfs*12 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel
- SART3 | c.2188C>A p.P730T (on ENST00000228284; = p.P712T on NM_014706.4) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SCFD1 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SCN4A | c.4017G>T p.Q1339H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SCYL2 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SERPINB5 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD2 | c.3584C>A p.P1195H | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.087); called by muse, mutect2
- SIPA1L1 | c.1001A>T p.Y334F | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC25A11 | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC30A6 | c.216del p.F72Lfs*3 | Frame Shift Del (DEL) | VAF 22/248 reads (9%) | called by mutect2, pindel
- SLIT3 | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMTNL2 | c.677del p.G226Afs*36 (on ENST00000389313 / NM_001114974.2; = p.G82Afs*36 on NM_198501.3) | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- SNRPA | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SNX1 | c.526T>C p.F176L | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOX8 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA2L | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- SPTLC2 | c.1505del p.P502Qfs*24 | Frame Shift Del (DEL) | VAF 44/489 reads (9%) | called by mutect2, pindel
- STX1B | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- TAS2R42 | c.774del p.F258Lfs*9 | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | called by mutect2, pindel
- TASOR | c.3866dup p.L1289Ffs*5 (on ENST00000355628 / NM_001365636.2; = p.L913Ffs*5 on NM_015224.3) | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- TASOR2 | c.3953A>G p.D1318G | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THAP9 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- THNSL1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM214 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TNC | c.4499del p.P1500Lfs*36 | Frame Shift Del (DEL) | VAF 20/246 reads (8%) | called by mutect2, pindel
- TRMT6 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- TSPAN9 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TTC28 | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2
- UBE3C | c.2754_2755del p.Y919Hfs*37 | Frame Shift Del (DEL) | VAF 38/143 reads (27%) | called by mutect2, pindel, varscan2
- USH2A | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- USP9X | c.3799A>T p.I1267F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VASH2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- VSIG10 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.648); called by muse, mutect2
- WDR64 | c.3012G>T p.E1004D | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK2 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- YY2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- ZBTB40 | c.3038A>G p.K1013R | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZC3H18 | c.2365A>G p.K789E | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF184 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ZNF423 | c.1286G>A p.S429N (on ENST00000563137 / NM_001379286.1; = p.S421N on NM_015069.4) | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF436 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 53/217 reads (24%) | called by muse, mutect2, varscan2
- ZNF511 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- ZNF532 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.203); called by muse, mutect2
- ZNF609 | c.2640del p.P882Lfs*30 | Frame Shift Del (DEL) | VAF 18/214 reads (8%) | called by mutect2, pindel
- ZNF865 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- AAAS | c.333C>T p.S111= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as rs146770218; ClinVar: uncertain significance; called by muse, mutect2
- ACOT8 | c.855G>A p.G285= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- ADAMTS2 | c.2451C>T p.T817= | Silent (SNP) | VAF 57/212 reads (27%) | catalogued as rs138564815; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD11 | c.7581C>T p.I2527= | Silent (SNP) | VAF 55/373 reads (15%) | catalogued as rs751599226, COSV99970339; called by muse, mutect2, varscan2
- AP2A1 | c.2067G>A p.P689= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as rs767411878; called by muse, mutect2, varscan2
- ARAP3 | c.1098G>A p.Q366= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV53348288; called by muse, mutect2
- ARHGAP4 | c.792C>T p.D264= | Silent (SNP) | VAF 25/258 reads (10%) | catalogued as rs1557104716, COSV63134042; called by muse, mutect2, varscan2
- ARHGEF4 | c.816C>T p.D272= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs779052727, COSV58122273; called by muse, mutect2
- ARMCX3 | c.435T>C p.A145= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- ARMCX6 | c.426C>A p.P142= | Silent (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- ASH1L | c.8730C>A p.T2910= (on ENST00000368346 / NM_001366177.2; = p.T2905= on NM_018489.3) | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- ASPH | c.798T>C p.Y266= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV62860423; called by muse, mutect2, varscan2
- ASPM | c.5112T>C p.A1704= | Silent (SNP) | VAF 17/241 reads (7%) | catalogued as rs1408275541; called by muse, mutect2
- AUTS2 | c.1635G>A p.P545= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as rs757756875, COSV61399821; called by muse, mutect2
- CACNA1F | c.5796G>A p.T1932= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as rs190606884; called by muse, mutect2
- CACNB2 | c.246C>T p.S82= (on ENST00000324631 / NM_201596.3; = p.S27= on NM_000724.4) | Silent (SNP) | VAF 133/446 reads (30%) | catalogued as rs758349246, COSV56619573; called by muse, mutect2, varscan2
- CCDC97 | c.295C>T p.L99= | Silent (SNP) | VAF 29/206 reads (14%) | catalogued as rs1385884488, COSV54190405; called by muse, mutect2, varscan2
- CDH24 | c.2355C>T p.S785= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1350018569; called by muse, mutect2, varscan2
- CDHR1 | c.2037T>C p.A679= | Silent (SNP) | VAF 39/333 reads (12%) | catalogued as COSV60565444; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.249C>T p.C83= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs755185617; called by muse, mutect2, varscan2
- CHRNA2 | c.288C>T p.I96= | Silent (SNP) | VAF 139/536 reads (26%) | catalogued as rs561008438, COSV53560055; called by muse, mutect2, varscan2
- CHRNE | c.951C>A p.L317= | Silent (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- CORO2B | c.411C>T p.S137= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV55950841, COSV99963304; called by muse, mutect2
- CSMD3 | c.1917G>A p.L639= (on ENST00000297405 / NM_001363185.1; = p.L535= on NM_052900.3) | Silent (SNP) | VAF 105/390 reads (27%) | catalogued as rs749285609, COSV99826464; called by muse, mutect2, varscan2
- CUBN | c.9165C>T p.Y3055= | Silent (SNP) | VAF 54/530 reads (10%) | catalogued as rs146539020; called by muse, mutect2, varscan2
- CYP2D7 | c.285C>T p.G95= | Silent (SNP) | VAF 28/383 reads (7%) | catalogued as rs755872488; called by muse, mutect2
- DACT2 | c.798C>T p.S266= | Silent (SNP) | VAF 23/208 reads (11%) | catalogued as rs765952509; called by muse, mutect2
- DACT2 | c.525G>A p.R175= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as rs751419662; called by muse, mutect2, varscan2
- DNAAF5 | c.726C>T p.S242= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs1372138610, COSV52419626; called by muse, mutect2
- DVL1 | c.1101G>A p.T367= | Silent (SNP) | VAF 75/261 reads (29%) | catalogued as rs775371452; called by muse, mutect2, varscan2
- ELF4 | c.585C>T p.I195= | Silent (SNP) | VAF 141/506 reads (28%) | catalogued as COSV57453397; called by muse, mutect2, varscan2
- ELL3 | c.174G>A p.L58= | Silent (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- ERCC6 | c.2097G>A p.T699= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs75166536, COSV63390216; called by muse, mutect2
- FES | c.579G>A p.A193= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as rs757886415, COSV51575888; called by muse, mutect2
- FGD3 | c.535C>T p.L179= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- FMOD | c.1014C>T p.D338= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs373594801; called by muse, mutect2, varscan2
- FREM1 | c.2196C>A p.A732= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- GATA1 | c.753T>C p.S251= | Silent (SNP) | VAF 43/366 reads (12%) | called by muse, mutect2, varscan2
- GFI1 | c.135C>T p.G45= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54043505; called by muse, mutect2
- GOLIM4 | c.1239G>A p.Q413= | Silent (SNP) | VAF 17/296 reads (6%) | called by muse, mutect2
- GRID2IP | c.3351C>T p.C1117= | Silent (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2
- HAND1 | c.447G>A p.V149= | Silent (SNP) | VAF 33/452 reads (7%) | catalogued as rs765762725; called by muse, mutect2
- HCN1 | c.2025C>T p.H675= | Silent (SNP) | VAF 28/303 reads (9%) | catalogued as COSV57533721; called by muse, mutect2
- HNRNPH1 | c.21T>C p.G7= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- HUWE1 | c.8532A>T p.A2844= | Silent (SNP) | VAF 110/341 reads (32%) | called by muse, mutect2, varscan2
- ITGA1 | c.3051G>A p.L1017= | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as rs775711684; called by muse, mutect2, varscan2
- KCNG1 | c.363G>A p.P121= | Silent (SNP) | VAF 19/704 reads (3%) | catalogued as COSV65370008; called by muse, mutect2
- KCNQ2 | c.2232G>A p.P744= (on ENST00000359125 / NM_172107.4; = p.P716= on NM_004518.6) | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs547655324, COSV100610122; ClinVar: likely benign; called by muse, mutect2
- KCNS1 | c.276C>T p.C92= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1391884538; called by muse, mutect2
- KIAA1109 | c.4278T>C p.I1426= | Silent (SNP) | VAF 32/380 reads (8%) | called by muse, mutect2
- KIF25 | c.762C>T p.P254= | Silent (SNP) | VAF 9/239 reads (4%) | catalogued as rs1007672911, COSV63027357; called by muse, mutect2
- KREMEN1 | c.543A>G p.A181= (on ENST00000407188; = p.A183= on NM_032045.5) | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- KRT74 | c.963C>T p.I321= | Silent (SNP) | VAF 31/311 reads (10%) | catalogued as rs749351683, COSV59771555; called by muse, mutect2, varscan2
- KRT86 | c.51C>A p.A17= | Silent (SNP) | VAF 16/546 reads (3%) | catalogued as COSV53293589, COSV99525072; called by muse, mutect2
- KRTAP24-1 | c.438C>T p.R146= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- KRTAP5-2 | c.66G>T p.G22= | Silent (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- LATS1 | c.2469T>C p.G823= | Silent (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- LINS1 | c.333T>C p.H111= | Silent (SNP) | VAF 40/252 reads (16%) | catalogued as rs1217367243; called by muse, mutect2, varscan2
- LMLN2 | c.1168C>T p.L390= | Silent (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- LYAR | c.180C>T p.G60= | Silent (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- MEIS2 | c.292C>T p.L98= (on ENST00000561208 / NM_170675.5; = p.L85= on NM_002399.3) | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- MPP4 | c.840C>T p.D280= | Silent (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- MRNIP | c.645A>G p.L215= | Silent (SNP) | VAF 12/349 reads (3%) | called by muse, mutect2
- MROH7 | c.693T>C p.N231= | Silent (SNP) | VAF 49/490 reads (10%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1311G>A p.V437= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- MTSS2 | c.1476C>T p.S492= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs775958994, COSV55382210; called by mutect2, varscan2
- MUC5B | c.9531C>T p.T3177= | Silent (SNP) | VAF 127/440 reads (29%) | catalogued as rs766161016; called by muse, mutect2, varscan2
- MYC | c.1044G>A p.S348= (on ENST00000377970; = p.S363= on NM_002467.6) | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as rs1305543869; called by muse, mutect2
- MYH14 | c.1221G>T p.G407= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as COSV51815937; called by muse, mutect2
- MYPN | c.1953A>G p.P651= | Silent (SNP) | VAF 29/353 reads (8%) | called by muse, mutect2
- NAA16 | c.1503C>T p.Y501= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as rs543151654, COSV65065724; called by muse, mutect2, varscan2
- NBPF12 | c.2517C>A p.L839= | Silent (SNP) | VAF 48/529 reads (9%) | called by muse, mutect2
- NEK4 | c.1494C>T p.C498= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1379086471; called by muse, mutect2, varscan2
- NFATC2 | c.567C>A p.P189= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- NID1 | c.1686C>A p.G562= | Silent (SNP) | VAF 14/303 reads (5%) | called by muse, mutect2
- NMT1 | c.1308C>T p.S436= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as rs766390878, COSV99364776; called by muse, mutect2
- NPC1 | c.37C>T p.L13= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as rs1567991697; called by muse, mutect2, varscan2
- NPHS1 | c.3075T>C p.A1025= | Silent (SNP) | VAF 80/284 reads (28%) | called by muse, mutect2, varscan2
- NTN5 | c.1326G>A p.T442= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1435104018; called by muse, mutect2
- NVL | c.1594C>T p.L532= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, varscan2
- OBSCN | c.16374C>T p.A5458= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- OR10A3 | c.252G>A p.V84= | Silent (SNP) | VAF 62/231 reads (27%) | catalogued as COSV62459403; called by muse, mutect2, varscan2
- ORAI2 | c.372C>T p.A124= | Silent (SNP) | VAF 11/265 reads (4%) | catalogued as rs920795151; called by muse, mutect2
- P2RX3 | c.873C>T p.G291= | Silent (SNP) | VAF 27/297 reads (9%) | called by muse, mutect2
- PCDHA9 | c.2199G>A p.A733= | Silent (SNP) | VAF 37/342 reads (11%) | catalogued as rs373763041; called by muse, mutect2, varscan2
- PCDHB11 | c.1365C>A p.S455= | Silent (SNP) | VAF 56/614 reads (9%) | called by muse, mutect2
- PCDHB3 | c.348C>T p.F116= | Silent (SNP) | VAF 12/243 reads (5%) | catalogued as rs943294647, COSV50563888, COSV50569842; called by muse, mutect2
- PCDHGA6 | c.975A>G p.P325= | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as rs1346702145; called by muse, mutect2, varscan2
- PCDHGA6 | c.1527C>T p.S509= | Silent (SNP) | VAF 28/298 reads (9%) | catalogued as rs748991083, COSV54054265, COSV99549714; called by muse, mutect2
- PDE4A | c.2190C>A p.A730= (on ENST00000380702 / NM_001111307.2; = p.A491= on NM_006202.3) | Silent (SNP) | VAF 45/400 reads (11%) | called by muse, mutect2, varscan2
- PGP | c.252G>T p.L84= | Silent (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- POLR2B | c.2673C>T p.D891= | Silent (SNP) | VAF 37/374 reads (10%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1941C>A p.T647= | Silent (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- PRLR | c.240C>T p.T80= | Silent (SNP) | VAF 25/371 reads (7%) | catalogued as rs779813878; called by muse, mutect2
- PRRC2A | c.1149C>T p.S383= | Silent (SNP) | VAF 31/398 reads (8%) | catalogued as rs779259807; called by muse, mutect2
- PRSS35 | c.810C>T p.D270= | Silent (SNP) | VAF 28/233 reads (12%) | catalogued as COSV63800777; called by muse, mutect2, varscan2
- PSD | c.1977G>A p.L659= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99192375; called by muse, mutect2
- PSMC4 | c.795C>T p.D265= | Silent (SNP) | VAF 33/303 reads (11%) | catalogued as rs758704054; called by muse, mutect2, varscan2
- PTPN3 | c.2172C>A p.T724= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV52705503; called by muse, mutect2
- RBM42 | c.582C>G p.G194= | Silent (SNP) | VAF 27/241 reads (11%) | called by muse, mutect2, varscan2
- RESF1 | c.4806T>C p.S1602= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- REXO1 | c.2481G>A p.E827= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- RIN2 | c.2167C>T p.L723= (on ENST00000255006 / NM_001242581.1; = p.L674= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, varscan2
- SAA2 | c.273G>A p.A91= | Silent (SNP) | VAF 22/247 reads (9%) | catalogued as rs200634677, COSV56777146; called by muse, mutect2
- SDHA | c.948C>T p.G316= | Silent (SNP) | VAF 36/592 reads (6%) | called by muse, mutect2
- SESTD1 | c.1122A>G p.Q374= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs746321121; called by muse, mutect2, varscan2
- SETD1B | c.1362G>C p.P454= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- SHANK1 | c.4536G>A p.S1512= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs779065002; called by muse, mutect2, varscan2
- SLC39A12 | c.453G>A p.R151= | Silent (SNP) | VAF 15/246 reads (6%) | catalogued as rs1554848426, COSV66202021; called by muse, mutect2
- SLC6A5 | c.2385T>C p.T795= | Silent (SNP) | VAF 20/552 reads (4%) | called by muse, mutect2
- SLITRK6 | c.2229A>G p.S743= | Silent (SNP) | VAF 17/336 reads (5%) | called by muse, mutect2
- SPARC | c.216C>T p.C72= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- SYN1 | c.1206C>T p.D402= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs1437174863; called by muse, mutect2
- TENM1 | c.3285C>G p.G1095= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV64447186; called by muse, mutect2, varscan2
- TENT5B | c.834C>T p.G278= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- TMEM151B | c.915G>A p.A305= | Silent (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- TMEM200C | c.387C>T p.G129= | Silent (SNP) | VAF 27/283 reads (10%) | catalogued as rs781557073; called by muse, mutect2
- TMEM38A | c.265C>T p.L89= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- TMEM63B | c.1932C>T p.I644= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as rs144265184; called by muse, mutect2, varscan2
- TRIP10 | c.606C>A p.A202= | Silent (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- TRPV3 | c.675G>A p.R225= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- UBA1 | c.2121G>C p.V707= | Silent (SNP) | VAF 12/411 reads (3%) | called by muse, mutect2
- UBE2E2 | c.345G>A p.P115= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs779913284, COSV59975446; called by muse, mutect2, varscan2
- VN1R1 | c.81A>G p.S27= | Silent (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- WDR41 | c.960T>C p.T320= | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- WEE2 | c.1581C>A p.T527= | Silent (SNP) | VAF 30/312 reads (10%) | catalogued as rs1417453337, COSV66879972; called by muse, mutect2
- ZCCHC14 | c.63G>A p.T21= (on ENST00000268616; = p.T158= on NM_015144.3) | Silent (SNP) | VAF 74/216 reads (34%) | catalogued as rs1477113989; called by muse, mutect2, varscan2
- ZMYM1 | c.1440C>T p.C480= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- ZNF143 | c.993C>T p.F331= | Silent (SNP) | VAF 31/308 reads (10%) | catalogued as rs147334022; called by muse, mutect2, varscan2
- ZNF672 | c.645G>A p.T215= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1249286614; called by muse, mutect2, varscan2
- ZNF853 | c.1383G>A p.P461= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as rs766550978; called by muse, mutect2
- AC009053.1 | n.865del | RNA (DEL) | VAF 32/189 reads (17%) | catalogued as rs1198030996; called by mutect2, pindel, varscan2
- AC055876.1 | n.330C>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- AC100872.1 | chr8:122670527 del A | 5'Flank (DEL) | VAF 22/125 reads (18%) | catalogued as rs750918355; called by mutect2, varscan2
- AL133467.6 | chr14:95668316 G>A | 5'Flank (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.323-13687C>T | Intron (SNP) | VAF 15/188 reads (8%) | catalogued as rs1435717850; called by muse, mutect2
- C10orf143 | c.69+2266G>A | Intron (SNP) | VAF 14/128 reads (11%) | catalogued as rs780491183, COSV69991449; called by muse, varscan2
- C15orf54 | n.650G>A | RNA (SNP) | VAF 26/259 reads (10%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.471A>G | RNA (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- CADM1 | c.1079-12143G>A | Intron (SNP) | VAF 24/316 reads (8%) | catalogued as rs778162315, COSV59018155; called by muse, mutect2
- CCDC162P | n.3276+80T>C | Intron (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- CD164L2 | c.*11C>T | 3'UTR (SNP) | VAF 9/130 reads (7%) | catalogued as rs921338453; called by muse, mutect2
- CD320 | c.-41C>A | 5'UTR (SNP) | VAF 72/244 reads (30%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+5328C>T | Intron (SNP) | VAF 13/169 reads (8%) | called by muse, mutect2
- CREB5 | chr7:28409821 C>T | 5'Flank (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CSAG3 | c.*7G>A | 3'UTR (SNP) | VAF 36/218 reads (17%) | catalogued as rs1275251354; called by mutect2, varscan2
- DDHD1 | c.422-26A>G | Intron (SNP) | VAF 28/244 reads (11%) | catalogued as rs1457046547; called by muse, mutect2, varscan2
- DYNC1I1 | c.-9-356C>T | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- EGFEM1P | n.982G>A | RNA (SNP) | VAF 59/244 reads (24%) | called by muse, mutect2, varscan2
- F5 | c.6346-51del | Intron (DEL) | VAF 25/146 reads (17%) | catalogued as rs71869143; called by mutect2, varscan2
- FOXP2 | c.*1880T>C | 3'UTR (SNP) | VAF 13/120 reads (11%) | catalogued as rs1419835324; called by muse, mutect2, varscan2
- GAS8 | c.*441C>G | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- GLP2R | c.*291del | 3'UTR (DEL) | VAF 60/188 reads (32%) | called by mutect2, pindel, varscan2
- GLT1D1 | c.413-16del | Intron (DEL) | VAF 24/192 reads (13%) | called by pindel, varscan2
- GSAP | c.-7C>T | 5'UTR (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- IGF2 | c.-4+157C>T | Intron (SNP) | VAF 8/110 reads (7%) | catalogued as rs1441033124, COSV56097371; called by muse, mutect2
- KCNQ3 | c.1465+50A>G | Intron (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- KRT6A | c.913-19A>G | Intron (SNP) | VAF 75/647 reads (12%) | called by muse, mutect2, varscan2
- LINC00174 | n.3244C>T | RNA (SNP) | VAF 23/195 reads (12%) | called by muse, mutect2, varscan2
- LTB4R2 | c.-5G>A | 5'UTR (SNP) | VAF 76/307 reads (25%) | catalogued as rs1190180646; called by muse, mutect2, varscan2
- MATR3 | c.-428T>C | 5'UTR (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- MEG3 | n.1199G>A | RNA (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- MGAM | c.4619-247G>T | Intron (SNP) | VAF 23/279 reads (8%) | catalogued as rs1312767848; called by muse, mutect2
- MOCS1 | c.*450C>T | 3'UTR (SNP) | VAF 11/318 reads (3%) | called by muse, mutect2
- MPV17 | c.280-29C>T | Intron (SNP) | VAF 16/570 reads (3%) | catalogued as rs1434404498; called by muse, mutect2
- MSH3 | c.-51G>A | 5'UTR (SNP) | VAF 15/185 reads (8%) | catalogued as rs771623781; called by muse, mutect2
- MTAP | c.120+50T>C | Intron (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- NDUFB1 | c.-5-42_-5-41insCA | Intron (INS) | VAF 5/41 reads (12%) | catalogued as rs1555412692; called by pindel, varscan2*
- NLN | c.1527+15T>C | Intron (SNP) | VAF 28/236 reads (12%) | catalogued as rs574103773, COSV66766392; called by muse, mutect2, varscan2
- NMNAT3 | c.294-2285G>A | Intron (SNP) | VAF 51/207 reads (25%) | catalogued as rs1438398233; called by muse, mutect2, varscan2
- PALLD | c.1965-13127G>A | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- PALLD | c.1965-12631G>A | Intron (SNP) | VAF 27/280 reads (10%) | called by muse, mutect2
- PDIA3P1 | n.1490C>T | RNA (SNP) | VAF 18/504 reads (4%) | called by muse, mutect2
- PIN1 | c.*239G>A | 3'UTR (SNP) | VAF 9/98 reads (9%) | catalogued as rs138973404; called by muse, mutect2
- PKD1L2 | n.2862G>A | RNA (SNP) | VAF 52/110 reads (47%) | catalogued as rs371510371; called by muse, mutect2, varscan2
- PKNOX1 | c.622+33_622+35del | Intron (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.343-24C>A | Intron (SNP) | VAF 52/496 reads (10%) | called by muse, mutect2
- PRPF31 | c.420+44C>T | Intron (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- RBBP7 | c.17-337G>A | Intron (SNP) | VAF 11/208 reads (5%) | catalogued as rs1355902037; called by muse, mutect2
- RN7SKP78 | chr10:6146467 C>T | 5'Flank (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2
- RNF126 | c.*206G>A | 3'UTR (SNP) | VAF 5/33 reads (15%) | catalogued as rs376174636; called by muse, mutect2
- RPL39 | c.3+28G>A | Intron (SNP) | VAF 13/47 reads (28%) | catalogued as COSV64294290; called by muse, mutect2, varscan2
- RUBCN | c.2646+62del | Intron (DEL) | VAF 25/196 reads (13%) | called by mutect2, pindel, varscan2
- SGSH | c.249+28del | Intron (DEL) | VAF 6/54 reads (11%) | catalogued as CD113451; called by mutect2, pindel
- SLC25A25 | c.1225+40del | Intron (DEL) | VAF 10/116 reads (9%) | catalogued as rs776026719; called by mutect2, pindel
- SLC5A1 | c.*17T>C | 3'UTR (SNP) | VAF 36/420 reads (9%) | called by muse, mutect2
- SLCO2B1 | c.-14G>A | 5'UTR (SNP) | VAF 8/126 reads (6%) | catalogued as rs1308246585; called by muse, mutect2
- SPAG16 | c.942+47077C>T | Intron (SNP) | VAF 7/108 reads (6%) | catalogued as rs958767501; called by muse, mutect2
- SPRED2 | c.373+413G>T | Intron (SNP) | VAF 23/225 reads (10%) | called by muse, mutect2, varscan2
- SSX2IP | c.1389+367del | Intron (DEL) | VAF 17/163 reads (10%) | catalogued as rs34993595; called by mutect2, pindel, varscan2
- UNC5D | c.*2414del | 3'UTR (DEL) | VAF 13/117 reads (11%) | catalogued as rs571534961; called by mutect2, varscan2
- ZBED8 | c.*2C>T | 3'UTR (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+44464del | Intron (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- ZNF462 | c.6013-44del | Intron (DEL) | VAF 20/236 reads (8%) | catalogued as rs1564113976, COSV99470567; called by mutect2, pindel
- ZNF767P | n.308G>A | RNA (SNP) | VAF 35/395 reads (9%) | called by muse, mutect2
